HCMI case HCM-WCMC-1281-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab18b5a1-e3b6-41f5-b0f7-22cd7d5a4e62

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1985; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, undifferentiated, NOS: ICD-O-3 morphology code: 8020/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 36.1 years (13,184 days); AJCC staging edition: 8th; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Doxorubicin + Methotrexate + Vinblastine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: MVAC-Growth Factor Regimen; Days to treatment start: 19 days; Days to treatment end: 91 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 368 days (1.0 years); Days to treatment end: 378 days (1.0 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 405 days (1.1 years); Days to treatment end: 531 days (1.5 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 476 days (1.3 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 519 days (1.4 years); Days to treatment end: 533 days (1.5 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 548 days (1.5 years); Days to treatment end: 579 days (1.6 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Sacituzumab Govitecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 586 days (1.6 years); Days to treatment end: 644 days (1.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 644 days (1.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 468.

Molecular and laboratory tests
- ALK mutation, nos: Negative.
- BRAF mutation, nos (Targeted Sequencing): Negative.
- CD274 (IHC): Positive.
- CDKN2A mutation, nos: Negative.
- EGFR: Negative.
- ERBB2 (IHC): Negative.
- GNAS mutation, nos: Negative.
- KRAS mutation, nos: Negative.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PIK3CA mutation, nos: Negative.
- PMS2 (IHC): Negative.
- PTEN mutation, nos: Negative.
- TP53 mutation, nos (Targeted Sequencing): Positive; Amino-acid change: c.586C>T, p.Arg196Ter.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 175.3 cm; BMI: 23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-WCMC-1281-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-1281-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
